Somatic mutation profile of tumor specimen ALCH-B2E3-TTP1-A (aliquot ALCH-B2E3-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2E3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 56.1 years (20,499 days).
Specimen ALCH-B2E3-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0173fe3-458f-4c89-a851-0699e30576ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2E3-NB1-A (Blood Derived Normal), aliquot ALCH-B2E3-NB1-A-2-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2119bfbb-66b7-469e-b4ea-afb79ce8582f

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 2, 3'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 40/436 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- B4GALNT4 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs887910167; called by muse, varscan2
- CDH26 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 22/157 reads (14%) | catalogued as COSV54842669; called by muse, mutect2, varscan2
- FAM177A1 | c.422G>A p.R141Q (on ENST00000382406 / NM_001289022.2; = p.R164Q on NM_173607.5) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs536518345, COSV55242236; called by muse, mutect2, varscan2
- KCNF1 | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV54462766; called by muse, mutect2
- KDM6A | c.2833-1G>T p.X945_splice | Splice Site (SNP) | VAF 42/175 reads (24%) | catalogued as rs1471773267, COSV65041827; called by muse, mutect2, varscan2
- LRIT1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs753319936, COSV64511886; called by muse, mutect2, varscan2
- PI4K2A | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298748190, COSV65702470; called by muse, mutect2, varscan2
- SLC1A6 | c.582C>A p.C194* | Nonsense Mutation (SNP) | VAF 24/220 reads (11%) | catalogued as COSV55670488; called by muse, mutect2, varscan2
- SLITRK6 | c.2405C>T p.T802I | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs1365338361; called by muse, mutect2
- WDR27 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1394568090, COSV61209533; called by muse, mutect2
- ACKR3 | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AHNAK | c.9954G>C p.L3318F | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- C16orf96 | c.1595G>C p.R532T | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.261); called by muse, varscan2
- LTBP3 | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 46/399 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- NKX2-1 | c.946dup p.H316Pfs*93 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- POGLUT3 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- RPL5 | c.719A>C p.Y240S | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TMEM63C | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); called by mutect2, varscan2
- TOGARAM2 | c.2387A>G p.K796R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- ZFHX3 | c.7801G>C p.A2601P | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF283 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 23/295 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.444); called by muse, mutect2
- ZNF343 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BCL11B | c.2241C>T p.N747= (on ENST00000357195 / NM_001282237.2; = p.N676= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/192 reads (16%) | called by muse, mutect2, varscan2
- EPHB1 | c.1170C>T p.R390= | Silent (SNP) | VAF 19/211 reads (9%) | catalogued as rs778438458, COSV101213159; called by muse, mutect2
- ERVFRD-1 | c.759C>T p.C253= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs776050141; called by muse, mutect2, varscan2
- SRRM2 | c.684G>A p.K228= | Silent (SNP) | VAF 22/219 reads (10%) | catalogued as rs550406093; called by muse, mutect2, varscan2
- TREH | c.576G>A p.T192= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as rs782713762; called by muse, mutect2
- ADAM9 | c.*45A>G | 3'UTR (SNP) | VAF 66/394 reads (17%) | catalogued as rs1379066878; called by mutect2, varscan2
